Somatic mutation profile of tumor specimen 0DE0TX from CCDI case PBBPEU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,364 days).
Specimen 0DE0TX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36ed4c67-b030-4888-af86-79faa3e20db8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb09fa6-0a60-4162-acbb-3d68267f035f

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MERTK | c.2309A>G p.E770G | Missense Mutation (SNP) | VAF 158/912 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775223365; called by muse, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, varscan2
- ITGB6 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 300/539 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, varscan2
- TOP3A | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.152); called by muse, varscan2
- TTN | c.68975T>G p.V22992G (on ENST00000591111; = p.V15568G on NM_003319.4) | Missense Mutation (SNP) | VAF 82/530 reads (15%) | PolyPhen probably damaging (0.999); called by muse, varscan2
- FRMPD3 | c.2313C>A p.A771= | Silent (SNP) | VAF 108/260 reads (42%) | called by muse, varscan2
- IQGAP3 | c.1944C>T p.N648= | Silent (SNP) | VAF 98/478 reads (21%) | catalogued as rs139780808; called by muse, varscan2
- LILRB2 | c.579G>A p.S193= | Silent (SNP) | VAF 88/540 reads (16%) | catalogued as rs370713732, COSV58744722; called by muse, varscan2
